TCGA case TCGA-HZ-7926 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2be42cc2-9b97-4821-afc2-d1e42eb3932d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Dead; Days to death: 518 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 57.6 years (21,024 days); Year of diagnosis: 2011; Method of diagnosis: Cytology; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 518 days (1.4 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 13; Tumor largest dimension diameter: 3.5 cm.
   Treatment given: Treatment type: Whipple.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 58.5 years (21,364 days); Days to diagnosis: 340 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 340 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 340 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 518 days (1.4 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 8.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HZ-7926-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-HZ-7926-01A-01-TS1: Section location: Top; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample TCGA-HZ-7926-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HZ-7926-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Alcohol history documented: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Pancreatic Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 518 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 518 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 340 days.
